Somatic mutation profile of tumor specimen TCGA-22-5483-01A (aliquot TCGA-22-5483-01A-01D-1817-08) from TCGA case TCGA-22-5483, project TCGA-LUSC (Lung Squamous Cell Carcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Upper lobe, lung; AJCC pathologic stage: Stage IIA; Age at diagnosis: 74.2 years (27,109 days).
Specimen TCGA-22-5483-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) f66d23d1-a9b7-4661-9dae-6b5e9351ea13.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-22-5483-11A (Solid Tissue Normal), aliquot TCGA-22-5483-11A-11D-1817-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/65b75274-abc2-415f-957e-7adbead720f9

The open-access MAF lists 228 somatic variants for this specimen: 174 protein-altering or splice-affecting, 48 silent, 6 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 155, Silent 48, Nonsense Mutation 6, Frame Shift Del 5, Splice Site 4, RNA 4, Intron 2, Frame Shift Ins 2, Splice Region 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- NFE2L2 | c.92G>C p.G31A | Missense Mutation (SNP) | VAF 33/90 reads (37%) | hotspot (GDC flag); SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as COSV67959995, COSV67960100, COSV67961494; called by muse, mutect2, varscan2
- RRM2B | c.208G>T p.D70Y | Missense Mutation (SNP) | VAF 13/85 reads (15%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.97); catalogued as rs515726183, CM1211105, COSV52565932; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- TP53 | c.993+1G>C p.X331_splice | Splice Site (SNP) | VAF 71/97 reads (73%) | hotspot (GDC flag); catalogued as rs11575997, CD002536, COSV52663229, COSV52699909, COSV52752826; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ABAT | c.332C>T p.A111V | Missense Mutation (SNP) | VAF 26/111 reads (23%) | SIFT tolerated (0.17); PolyPhen benign (0.311); catalogued as COSV99190869; called by muse, mutect2, varscan2
- ADGRG6 | c.2009C>T p.S670L | Missense Mutation (SNP) | VAF 49/124 reads (40%) | SIFT deleterious (0.01); PolyPhen benign (0.092); catalogued as COSV99745583; called by muse, mutect2, varscan2
- ADM5 | c.26T>C p.L9P | Missense Mutation (SNP) | VAF 41/219 reads (19%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.907); catalogued as COSV99773185; called by muse, mutect2, varscan2
- ALDOA | c.1223G>C p.S408T (on ENST00000642816 / NM_001243177.4; = p.S354T on NM_184041.5) | Missense Mutation (SNP) | VAF 60/146 reads (41%) | SIFT tolerated (0.17); PolyPhen benign (0.049); catalogued as rs766537404, COSV100581881, COSV57633832; called by muse, mutect2, varscan2
- ALPK2 | c.809T>A p.I270N | Missense Mutation (SNP) | VAF 109/247 reads (44%) | SIFT deleterious (0); PolyPhen possibly damaging (0.757); catalogued as COSV100864018; called by muse, mutect2, varscan2
- ARHGEF10 | c.1358A>T p.E453V (on ENST00000398564; = p.E428V on NM_014629.4) | Missense Mutation (SNP) | VAF 24/60 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.931); catalogued as rs759111033, COSV100033543; called by muse, mutect2, varscan2
- ARHGEF9 | c.31G>C p.V11L | Missense Mutation (SNP) | VAF 35/54 reads (65%) | SIFT deleterious (0.05); PolyPhen benign (0.283); catalogued as COSV53635605, COSV99491282; called by muse, mutect2, varscan2
- ARMC5 | c.340G>C p.V114L | Missense Mutation (SNP) | VAF 24/37 reads (65%) | SIFT tolerated, low confidence (0.2); PolyPhen benign (0.015); catalogued as rs1050026325, COSV99192303, COSV99192980; called by mutect2, varscan2
- ATP13A5 | c.1900T>A p.C634S | Missense Mutation (SNP) | VAF 53/142 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV100664653; called by muse, mutect2, varscan2
- BIVM-ERCC5 | c.1760G>T p.S587I | Missense Mutation (SNP) | VAF 47/65 reads (72%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs1393977944, COSV100863574; called by muse, mutect2, varscan2
- C12orf40 | c.1478G>T p.S493I | Missense Mutation (SNP) | VAF 22/60 reads (37%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.976); catalogued as COSV100209561; called by muse, mutect2, varscan2
- CACNG8 | c.76G>A p.V26M | Missense Mutation (SNP) | VAF 15/29 reads (52%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.505); catalogued as COSV99554811; called by muse, mutect2, varscan2
- CCDC102B | c.986G>T p.G329V | Missense Mutation (SNP) | VAF 21/65 reads (32%) | SIFT tolerated (0.24); PolyPhen benign (0.045); catalogued as rs746426458, COSV100101805; called by muse, mutect2, varscan2
- CCKAR | c.694A>T p.I232F | Missense Mutation (SNP) | VAF 53/164 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99810050; called by muse, mutect2, varscan2
- CCR6 | c.137G>C p.R46T | Missense Mutation (SNP) | VAF 76/227 reads (33%) | SIFT tolerated (0.31); PolyPhen benign (0.006); catalogued as COSV100550951; called by muse, mutect2, varscan2
- CENPF | c.24G>A p.W8* | Nonsense Mutation (SNP) | VAF 57/136 reads (42%) | catalogued as COSV100871442; called by muse, mutect2, varscan2
- CENPF | c.2767G>A p.E923K | Missense Mutation (SNP) | VAF 84/170 reads (49%) | SIFT tolerated (0.15); PolyPhen benign (0.071); catalogued as COSV100871443; called by muse, mutect2, varscan2
- CER1 | c.529G>A p.E177K | Missense Mutation (SNP) | VAF 33/46 reads (72%) | SIFT deleterious (0); PolyPhen possibly damaging (0.763); catalogued as rs755263838, COSV101097736, COSV101097777; called by muse, varscan2
- CFAP299 | c.598G>T p.D200Y | Missense Mutation (SNP) | VAF 20/90 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100811250; called by muse, varscan2
- CHD7 | c.5865G>T p.R1955S | Missense Mutation (SNP) | VAF 32/147 reads (22%) | SIFT tolerated (0.28); PolyPhen benign (0.031); catalogued as COSV101417955; called by muse, mutect2, varscan2
- CHRM2 | c.101G>C p.S34T | Missense Mutation (SNP) | VAF 47/115 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV100280579; called by muse, mutect2, varscan2
- CIBAR1 | c.652T>G p.L218V | Missense Mutation (SNP) | VAF 7/15 reads (47%) | SIFT deleterious (0); PolyPhen possibly damaging (0.868); catalogued as COSV100844619; called by muse, mutect2, varscan2
- CKAP2L | c.1334C>T p.T445I | Missense Mutation (SNP) | VAF 136/355 reads (38%) | SIFT deleterious (0.03); PolyPhen benign (0.232); catalogued as COSV100198401; called by muse, mutect2, varscan2
- CKS2 | c.181G>T p.E61* | Nonsense Mutation (SNP) | VAF 19/171 reads (11%) | catalogued as COSV100068783; called by muse, mutect2, varscan2
- CLEC4A | c.164T>A p.L55Q | Missense Mutation (SNP) | VAF 33/63 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV99983479; called by muse, mutect2, varscan2
- CNTNAP4 | c.1905G>T p.Q635H | Missense Mutation (SNP) | VAF 11/22 reads (50%) | SIFT tolerated (0.12); PolyPhen benign (0.009); catalogued as COSV56690258; called by muse, mutect2, varscan2
- COL19A1 | c.263C>A p.T88N | Missense Mutation (SNP) | VAF 14/62 reads (23%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.709); catalogued as COSV100504902; called by muse, mutect2, varscan2
- COL19A1 | c.337A>G p.K113E | Missense Mutation (SNP) | VAF 48/136 reads (35%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.591); catalogued as COSV100504904; called by muse, mutect2, varscan2
- CPA3 | c.410C>G p.P137R | Missense Mutation (SNP) | VAF 52/175 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV99935906; called by muse, mutect2, varscan2
- CR2 | c.675G>C p.K225N | Missense Mutation (SNP) | VAF 51/143 reads (36%) | SIFT deleterious (0.03); PolyPhen benign (0.281); catalogued as COSV100889510; called by muse, mutect2, varscan2
- CRIM1 | c.806C>A p.P269H | Missense Mutation (SNP) | VAF 11/213 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.628); catalogued as COSV99752166; called by muse, mutect2
- CRMP1 | c.593A>G p.H198R | Missense Mutation (SNP) | VAF 37/75 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100271233; called by muse, mutect2, varscan2
- CUEDC1 | c.398C>G p.P133R | Missense Mutation (SNP) | VAF 119/199 reads (60%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100804634, COSV64227368; called by muse, mutect2, varscan2
- DNAH3 | c.1121T>A p.L374Q | Missense Mutation (SNP) | VAF 67/270 reads (25%) | SIFT tolerated (0.34); PolyPhen benign (0.293); catalogued as COSV99764559; called by muse, mutect2, varscan2
- EEF1AKNMT | c.1697G>A p.R566Q (on ENST00000361735 / NM_015935.5; = p.R480Q on NM_014955.3) | Missense Mutation (SNP) | VAF 41/102 reads (40%) | SIFT tolerated (0.64); PolyPhen benign (0.007); catalogued as rs200264969, COSV100675746; called by muse, mutect2, varscan2
- ELN | c.914C>T p.A305V | Missense Mutation (SNP) | VAF 53/190 reads (28%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.99); catalogued as rs782396192, COSV52710888; called by muse, mutect2, varscan2
- EPHA5 | c.315G>T p.M105I | Missense Mutation (SNP) | VAF 64/204 reads (31%) | SIFT deleterious (0.02); PolyPhen benign (0.372); catalogued as rs907974082, COSV99078211, COSV99895480; called by muse, mutect2, varscan2
- ERICH6 | c.1779C>A p.D593E | Missense Mutation (SNP) | VAF 97/236 reads (41%) | SIFT tolerated (0.27); PolyPhen possibly damaging (0.805); catalogued as COSV99901287; called by muse, mutect2, varscan2
- ESS2 | c.29C>A p.S10Y | Missense Mutation (SNP) | VAF 7/32 reads (22%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.003); catalogued as COSV99324017; called by muse, mutect2
- EXOC6B | c.116C>G p.S39C | Missense Mutation (SNP) | VAF 28/181 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as COSV99722557; called by muse, mutect2, varscan2
- FAM135B | c.3205C>G p.Q1069E | Missense Mutation (SNP) | VAF 21/81 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.952); catalogued as COSV52734419, COSV99417760; called by muse, mutect2, varscan2
- FAM71A | c.1550C>A p.S517Y | Missense Mutation (SNP) | VAF 56/123 reads (46%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.96); catalogued as COSV54234848, COSV99674314; called by muse, varscan2
- FBN3 | c.3887C>G p.S1296C | Missense Mutation (SNP) | VAF 57/155 reads (37%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.911); catalogued as COSV99559495; called by muse, mutect2, varscan2
- FLG | c.11576A>T p.Q3859L | Missense Mutation (SNP) | VAF 171/448 reads (38%) | SIFT deleterious (0.04); PolyPhen benign (0.187); catalogued as COSV100910377; called by muse, mutect2, varscan2
- FLRT2 | c.1381T>A p.L461I | Missense Mutation (SNP) | VAF 6/144 reads (4%) | SIFT tolerated (0.26); PolyPhen possibly damaging (0.668); catalogued as COSV100419903; called by muse, mutect2
- FNDC1 | c.1846G>T p.A616S | Missense Mutation (SNP) | VAF 32/70 reads (46%) | SIFT tolerated, low confidence (0.26); PolyPhen benign (0.006); catalogued as COSV99794689; called by muse, mutect2, varscan2
- FOXA2 | c.367G>T p.G123C (on ENST00000377115 / NM_153675.3; = p.G129C on NM_021784.5) | Missense Mutation (SNP) | VAF 46/99 reads (46%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.696); catalogued as COSV101008219; called by muse, mutect2, varscan2
- GLP2R | c.1056A>T p.T352= | Splice Region (SNP) | VAF 134/190 reads (71%) | catalogued as COSV99301463; called by muse, mutect2, varscan2
- GPR63 | c.1204C>G p.R402G | Missense Mutation (SNP) | VAF 64/170 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV100013091, COSV57740915; called by muse, mutect2, varscan2
- GTF2I | c.752A>G p.Y251C | Missense Mutation (SNP) | VAF 33/55 reads (60%) | SIFT tolerated (0.13); PolyPhen benign (0.066); catalogued as rs1554402445, COSV100259385; called by muse, mutect2, varscan2
- GXYLT2 | c.999C>G p.C333W | Missense Mutation (SNP) | VAF 12/28 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101274602; called by muse, mutect2, varscan2
- HECW1 | c.1985C>A p.P662H | Missense Mutation (SNP) | VAF 39/72 reads (54%) | SIFT tolerated, low confidence (0.36); PolyPhen benign (0.005); catalogued as COSV101222614, COSV101222856; called by muse, mutect2, varscan2
- HNF1A | c.245C>A p.T82K | Missense Mutation (SNP) | VAF 11/25 reads (44%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.497); catalogued as CM067041, COSV99981920; called by muse, mutect2, varscan2
- HOXD1 | c.84C>G p.C28W | Missense Mutation (SNP) | VAF 17/41 reads (41%) | SIFT deleterious (0); PolyPhen benign (0.157); catalogued as COSV100514064; called by muse, mutect2, varscan2
- IFT140 | c.3641A>C p.Q1214P | Missense Mutation (SNP) | VAF 9/25 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100794111; called by muse, mutect2, varscan2
- IFT74 | c.587C>T p.A196V | Missense Mutation (SNP) | VAF 29/45 reads (64%) | SIFT tolerated (0.23); PolyPhen benign (0.31); catalogued as rs995864839, COSV101195762; called by muse, mutect2, varscan2
- IKBKE | c.1001T>A p.I334N | Missense Mutation (SNP) | VAF 122/263 reads (46%) | SIFT tolerated (0.17); PolyPhen benign (0.025); catalogued as COSV100898061; called by muse, mutect2, varscan2
- IQSEC1 | c.190G>T p.G64* | Nonsense Mutation (SNP) | VAF 24/37 reads (65%) | catalogued as COSV99831184; called by muse, mutect2, varscan2
- ITGAM | c.3202G>T p.V1068L (on ENST00000648685 / NM_001145808.2; = p.V1067L on NM_000632.4) | Missense Mutation (SNP) | VAF 17/51 reads (33%) | SIFT tolerated (0.13); PolyPhen benign (0.104); catalogued as rs374690908; called by muse, mutect2, varscan2
- KCNE2 | c.256C>T p.Q86* | Nonsense Mutation (SNP) | VAF 32/47 reads (68%) | catalogued as COSV99285638; called by muse, mutect2, varscan2
- KDM6A | c.521G>T p.G174V | Missense Mutation (SNP) | VAF 56/75 reads (75%) | SIFT deleterious (0); PolyPhen possibly damaging (0.824); catalogued as COSV100937858, COSV65038427; called by muse, mutect2, varscan2
- KIF1A | c.1690G>A p.D564N | Missense Mutation (SNP) | VAF 24/67 reads (36%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.562); catalogued as COSV100239586; called by muse, mutect2, varscan2
- KIF6 | c.2278C>A p.H760N | Missense Mutation (SNP) | VAF 34/67 reads (51%) | SIFT tolerated (0.52); PolyPhen benign (0); catalogued as COSV99756815; called by muse, mutect2, varscan2
- KLHL4 | c.1456G>T p.G486C | Missense Mutation (SNP) | VAF 57/68 reads (84%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV64139273, COSV64146543; called by muse, mutect2, varscan2
- LAMA1 | c.1873G>T p.G625C | Missense Mutation (SNP) | VAF 35/101 reads (35%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as COSV101054677; called by muse, mutect2, varscan2
- LAMP3 | c.572C>A p.A191D | Missense Mutation (SNP) | VAF 113/302 reads (37%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.697); catalogued as rs1321441291, COSV99660271; called by muse, mutect2, varscan2
- LIN9 | c.1762C>A p.H588N (on ENST00000366808 / NM_001270410.2; = p.H533N on NM_173083.3 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 44/118 reads (37%) | SIFT deleterious (0.01); PolyPhen benign (0.209); catalogued as COSV100066919, COSV60245752; called by muse, mutect2, varscan2
- LINGO1 | c.310G>A p.E104K | Missense Mutation (SNP) | VAF 9/31 reads (29%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.605); catalogued as COSV100796260; called by muse, mutect2, varscan2
- LRP1B | c.4778A>G p.Y1593C | Missense Mutation (SNP) | VAF 35/74 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV101250858; called by muse, mutect2, varscan2
- MAGEB1 | c.616G>T p.G206C | Missense Mutation (SNP) | VAF 16/22 reads (73%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.995); catalogued as COSV100974795; called by muse, mutect2, varscan2
- MAGEL2 | c.2224C>A p.R742S | Missense Mutation (SNP) | VAF 25/61 reads (41%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.593); catalogued as COSV100045670, COSV58568250; called by muse, mutect2, varscan2
- MAP2K3 | c.546C>A p.S182R (on ENST00000342679 / NM_145109.3; = p.S153R on NM_002756.4) | Missense Mutation (SNP) | VAF 9/64 reads (14%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.795); catalogued as COSV100383259; called by muse, mutect2, varscan2
- MC5R | c.335G>C p.R112P | Missense Mutation (SNP) | VAF 54/122 reads (44%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.95); catalogued as COSV100228895, COSV61255874; called by muse, mutect2, varscan2
- MEP1A | c.152G>C p.G51A | Missense Mutation (SNP) | VAF 65/162 reads (40%) | SIFT deleterious (0); PolyPhen possibly damaging (0.629); catalogued as COSV100042246; called by muse, mutect2, varscan2
- MFSD11 | c.136G>C p.G46R | Missense Mutation (SNP) | VAF 20/98 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs377197459; called by muse, mutect2, varscan2
- MMP25 | c.620C>T p.T207I | Missense Mutation (SNP) | VAF 25/91 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.522); catalogued as COSV100339295; called by muse, mutect2, varscan2
- MOCS1 | c.757G>T p.G253C | Missense Mutation (SNP) | VAF 29/71 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100418368, COSV57934353; called by muse, mutect2, varscan2
- MRPL54 | c.215C>T p.A72V | Missense Mutation (SNP) | VAF 5/78 reads (6%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.999); catalogued as COSV100349528; called by muse, mutect2
- MS4A6A | c.359G>C p.G120A | Missense Mutation (SNP) | VAF 53/99 reads (54%) | SIFT tolerated (0.95); PolyPhen benign (0.009); catalogued as COSV100124502, COSV100124941, COSV60618722; called by muse, mutect2, varscan2
- MS4A8 | c.143G>C p.G48A | Missense Mutation (SNP) | VAF 34/108 reads (31%) | SIFT tolerated (0.17); PolyPhen benign (0.264); catalogued as COSV100282352; called by muse, mutect2, varscan2
- MUC6 | c.3944C>A p.P1315Q | Missense Mutation (SNP) | VAF 27/106 reads (25%) | SIFT deleterious (0.01); PolyPhen benign (0.073); catalogued as COSV101424363; called by muse, mutect2, varscan2
- MYO1B | c.880G>T p.G294C | Missense Mutation (SNP) | VAF 64/148 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV100268478; called by muse, mutect2, varscan2
- MYO7A | c.2608G>A p.E870K | Missense Mutation (SNP) | VAF 8/36 reads (22%) | SIFT tolerated (0.52); PolyPhen probably damaging (0.987); catalogued as COSV101289015, COSV101289186; called by mutect2, varscan2
- NCAPG2 | c.17C>A p.T6K | Missense Mutation (SNP) | VAF 27/99 reads (27%) | SIFT tolerated (0.07); PolyPhen benign (0.089); catalogued as COSV100690184; called by muse, mutect2, varscan2
- NDN | c.424C>A p.R142S | Missense Mutation (SNP) | VAF 64/135 reads (47%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.987); catalogued as COSV100086175, COSV59358609; called by muse, mutect2, varscan2
- NELL1 | c.568C>T p.L190F | Missense Mutation (SNP) | VAF 36/75 reads (48%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.951); catalogued as COSV100118265; called by muse, varscan2
- NLGN1 | c.223G>C p.G75R | Missense Mutation (SNP) | VAF 79/197 reads (40%) | SIFT tolerated (0.49); PolyPhen benign (0.076); catalogued as COSV100848677, COSV64340835; called by muse, mutect2, varscan2
- OR4C12 | c.595G>T p.V199L | Missense Mutation (SNP) | VAF 41/88 reads (47%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.001); catalogued as rs545187798, COSV100078195; called by muse, mutect2, varscan2
- OTOA | c.41T>C p.L14P | Missense Mutation (SNP) | VAF 40/148 reads (27%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.875); catalogued as COSV99623413; called by muse, mutect2, varscan2
- PAPOLB | c.653T>C p.I218T | Missense Mutation (SNP) | VAF 89/173 reads (51%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.815); catalogued as COSV101271212; called by muse, mutect2, varscan2
- PCDH11Y | c.3136C>G p.R1046G | Missense Mutation (SNP) | VAF 56/83 reads (67%) | SIFT deleterious (0); PolyPhen benign (0.173); catalogued as COSV99290362; called by muse, mutect2, varscan2
- PCDH7 | c.1950A>C p.E650D | Missense Mutation (SNP) | VAF 46/146 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV100687358; called by muse, mutect2, varscan2
- PCDHA5 | c.1936C>A p.L646I | Missense Mutation (SNP) | VAF 72/87 reads (83%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.923); catalogued as COSV100972060; called by muse, mutect2, varscan2
- PCDHGB1 | c.1572C>G p.F524L | Missense Mutation (SNP) | VAF 82/113 reads (73%) | SIFT tolerated (0.44); PolyPhen benign (0.246); catalogued as rs1230922567, COSV53903027, COSV99529027; called by muse, mutect2, varscan2
- PCDHGC3 | c.559C>T p.R187W | Missense Mutation (SNP) | VAF 44/65 reads (68%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.987); catalogued as COSV52748030; called by muse, mutect2, varscan2
- PEX1 | c.1010A>T p.K337M | Missense Mutation (SNP) | VAF 48/122 reads (39%) | SIFT deleterious (0); PolyPhen benign (0.417); catalogued as COSV99951816; called by muse, mutect2, varscan2
- PEX5L | c.1521C>A p.D507E | Missense Mutation (SNP) | VAF 70/201 reads (35%) | SIFT tolerated (0.05); PolyPhen benign (0.095); catalogued as COSV99827750; called by muse, mutect2, varscan2
- PFKFB1 | c.611A>G p.Y204C | Missense Mutation (SNP) | VAF 25/36 reads (69%) | PolyPhen probably damaging (1); catalogued as COSV100895571; called by muse, mutect2, varscan2
- PKD1 | c.4491C>A p.S1497R | Missense Mutation (SNP) | VAF 26/79 reads (33%) | SIFT tolerated (0.36); PolyPhen benign (0.02); catalogued as COSV99236997; called by muse, mutect2, varscan2
- PPFIA2 | c.314C>A p.A105E | Missense Mutation (SNP) | VAF 11/30 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as COSV100331341; called by muse, mutect2, varscan2
- PPM1J | c.1282G>A p.D428N | Missense Mutation (SNP) | VAF 11/139 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99588046; called by muse, mutect2
- PRDM16 | c.3404C>T p.A1135V | Missense Mutation (SNP) | VAF 11/13 reads (85%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.956); catalogued as COSV99575261; called by muse, mutect2, varscan2
- PROX1 | c.124T>C p.F42L | Missense Mutation (SNP) | VAF 62/151 reads (41%) | SIFT tolerated, low confidence (0.43); PolyPhen benign (0.007); catalogued as COSV99798572; called by muse, mutect2, varscan2
- PUS7L | c.1695C>A p.D565E | Missense Mutation (SNP) | VAF 58/133 reads (44%) | SIFT tolerated (0.6); PolyPhen benign (0.021); catalogued as COSV100786444; called by muse, mutect2, varscan2
- RBPMS | c.247G>C p.G83R | Missense Mutation (SNP) | VAF 51/153 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99823561; called by muse, mutect2, varscan2
- RCE1 | c.68C>G p.S23W | Missense Mutation (SNP) | VAF 4/8 reads (50%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.677); catalogued as COSV100546933; called by muse, mutect2, varscan2
- RCSD1 | c.598G>C p.E200Q | Missense Mutation (SNP) | VAF 57/144 reads (40%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.903); catalogued as COSV100827531, COSV100827784; called by muse, mutect2, varscan2
- RGP1 | c.737G>A p.G246E | Missense Mutation (SNP) | VAF 69/101 reads (68%) | SIFT tolerated (0.09); PolyPhen benign (0.005); catalogued as rs757267341, COSV100960069; called by muse, mutect2, varscan2
- RP1 | c.3194T>C p.V1065A | Missense Mutation (SNP) | VAF 48/100 reads (48%) | SIFT tolerated (0.21); PolyPhen benign (0.006); catalogued as COSV99606005; called by muse, mutect2, varscan2
- RPE | c.433C>T p.P145S (on ENST00000359429 / NM_001318926.1; = p.P95S on NM_006916.2) | Missense Mutation (SNP) | VAF 79/173 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99910043; called by muse, mutect2, varscan2
- RPIA | c.831G>C p.M277I | Missense Mutation (SNP) | VAF 33/73 reads (45%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.69); catalogued as COSV99375836; called by muse, mutect2, varscan2
- SASH1 | c.1134A>T p.E378D | Missense Mutation (SNP) | VAF 18/45 reads (40%) | SIFT tolerated, low confidence (0.35); PolyPhen benign (0.001); catalogued as COSV100820849; called by muse, mutect2, varscan2
- SCAPER | c.940G>T p.G314C | Missense Mutation (SNP) | VAF 62/158 reads (39%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.646); catalogued as rs754216073, COSV100236884; called by muse, mutect2, varscan2
- SCGN | c.319A>C p.S107R | Missense Mutation (SNP) | VAF 66/84 reads (79%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV100618623; called by muse, mutect2, varscan2
- SEMA3D | c.65T>C p.L22S | Missense Mutation (SNP) | VAF 36/100 reads (36%) | SIFT tolerated (0.17); PolyPhen benign (0.015); catalogued as rs1476749494, COSV99405657; called by muse, mutect2, varscan2
- SHANK1 | c.6245T>C p.L2082P | Missense Mutation (SNP) | VAF 40/82 reads (49%) | SIFT tolerated (0.05); PolyPhen benign (0.003); catalogued as COSV99520027; called by mutect2, varscan2
- SHC3 | c.759C>G p.I253M | Missense Mutation (SNP) | VAF 72/174 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101011850, COSV65437654; called by muse, mutect2, varscan2
- SIN3A | c.748G>A p.V250I | Missense Mutation (SNP) | VAF 9/93 reads (10%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV100845010; called by muse, mutect2, varscan2
- SLC12A7 | c.2539G>T p.D847Y | Missense Mutation (SNP) | VAF 12/43 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99369186; called by muse, mutect2, varscan2
- SLC2A13 | c.299G>A p.G100E | Missense Mutation (SNP) | VAF 6/15 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as COSV99785738; called by muse, mutect2
- SLC35E3 | c.335C>G p.P112R | Missense Mutation (SNP) | VAF 94/212 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99971447; called by muse, mutect2, varscan2
- SLC37A2 | c.315T>A p.S105R | Missense Mutation (SNP) | VAF 82/304 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as rs1457197143, COSV100016870; called by muse, mutect2, varscan2
- SLCO1C1 | c.1020A>T p.R340S | Missense Mutation (SNP) | VAF 18/34 reads (53%) | SIFT tolerated (0.14); PolyPhen benign (0.007); catalogued as COSV99858312; called by muse, mutect2, varscan2
- SLITRK3 | c.2285A>G p.E762G | Missense Mutation (SNP) | VAF 68/172 reads (40%) | SIFT tolerated (0.1); PolyPhen benign (0.055); catalogued as COSV99578268; called by muse, mutect2, varscan2
- SNRNP40 | c.409G>C p.D137H | Missense Mutation (SNP) | VAF 22/275 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99744988; called by muse, mutect2
- SPATA5 | c.1838C>T p.A613V | Missense Mutation (SNP) | VAF 39/126 reads (31%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.967); catalogued as COSV56775208; called by muse, mutect2, varscan2
- SPP1 | c.731G>A p.R244K (on ENST00000395080 / NM_001040058.2; = p.R230K on NM_000582.2) | Missense Mutation (SNP) | VAF 45/118 reads (38%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV99420799; called by muse, mutect2, varscan2
- SYNJ2 | c.2963T>G p.V988G | Missense Mutation (SNP) | VAF 81/230 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.588); catalogued as rs779341189, COSV100839991; called by muse, mutect2, varscan2
- TAAR9 | c.137C>T p.A46V | Missense Mutation (SNP) | VAF 31/95 reads (33%) | SIFT deleterious (0.05); PolyPhen benign (0.434); catalogued as COSV101453272; called by muse, mutect2, varscan2
- TDP1 | c.827G>C p.R276P | Missense Mutation (SNP) | VAF 57/85 reads (67%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100187521; called by muse, varscan2
- TECTA | c.1638T>A p.F546L | Missense Mutation (SNP) | VAF 49/206 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV99878313; called by muse, mutect2, varscan2
- TGM6 | c.1880C>G p.T627R | Missense Mutation (SNP) | VAF 120/331 reads (36%) | SIFT tolerated (0.2); PolyPhen benign (0.007); catalogued as COSV99171664; called by muse, mutect2, varscan2
- THSD7B | c.1200G>T p.R400S | Missense Mutation (SNP) | VAF 22/69 reads (32%) | SIFT tolerated (0.28); PolyPhen possibly damaging (0.755); catalogued as COSV55716939; called by muse, mutect2, varscan2
- TLX3 | c.35C>T p.P12L | Missense Mutation (SNP) | VAF 15/23 reads (65%) | SIFT tolerated (0.18); PolyPhen benign (0.062); catalogued as COSV51542403; called by muse, mutect2, varscan2
- TMEM98 | c.473G>A p.R158Q | Missense Mutation (SNP) | VAF 44/112 reads (39%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.932); catalogued as COSV55583630; called by muse, mutect2, varscan2
- TNXB | c.5420C>A p.T1807K (on ENST00000647633; = p.T1560K on NM_019105.8 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 8/27 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV100925701, COSV64486895; called by muse, mutect2, varscan2
- TRAF3 | c.232G>T p.A78S | Missense Mutation (SNP) | VAF 67/76 reads (88%) | SIFT tolerated (0.54); PolyPhen benign (0.001); catalogued as COSV100693401; called by muse, mutect2, varscan2
- TRIM55 | c.891G>T p.M297I | Missense Mutation (SNP) | VAF 22/80 reads (28%) | SIFT tolerated (0.11); PolyPhen benign (0.014); catalogued as COSV52550448, COSV99396430; called by muse, mutect2
- TRIM55 | c.892G>T p.E298* | Nonsense Mutation (SNP) | VAF 24/82 reads (29%) | catalogued as COSV52550283, COSV99396434; called by muse, mutect2
- TRPM3 | c.2772+1G>A p.X924_splice (on ENST00000357533 / NM_001366142.2; = p.X767_splice on NM_020952.6) | Splice Site (SNP) | VAF 26/69 reads (38%) | catalogued as COSV100676416, COSV62581098; called by muse, mutect2, varscan2
- VIL1 | c.82C>A p.Q28K | Missense Mutation (SNP) | VAF 82/235 reads (35%) | SIFT tolerated (0.71); PolyPhen benign (0.001); catalogued as COSV99945170; called by muse, mutect2, varscan2
- WDFY3 | c.1124-1G>T p.X375_splice | Splice Site (SNP) | VAF 24/67 reads (36%) | catalogued as COSV99881631; called by muse, mutect2, varscan2
- WDR72 | c.115G>C p.G39R | Missense Mutation (SNP) | VAF 49/158 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100854114, COSV100854969, COSV64744006; called by muse, mutect2, varscan2
- WSB1 | c.559G>C p.V187L | Missense Mutation (SNP) | VAF 12/200 reads (6%) | SIFT tolerated (0.06); PolyPhen benign (0.389); catalogued as COSV99285840; called by muse, mutect2
- WWC2 | c.3002G>A p.R1001H | Missense Mutation (SNP) | VAF 27/95 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV101330845; called by muse, mutect2, varscan2
- XRN1 | c.3325G>T p.V1109F | Missense Mutation (SNP) | VAF 35/97 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV99377056; called by muse, mutect2, varscan2
- ZBED1 | c.58C>T p.R20C | Missense Mutation (SNP) | VAF 80/304 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV58134529; called by muse, mutect2, varscan2
- ZC3H3 | c.298G>T p.G100W | Missense Mutation (SNP) | VAF 111/186 reads (60%) | SIFT deleterious (0); PolyPhen possibly damaging (0.715); catalogued as rs542311174, COSV99367273; called by muse, mutect2, varscan2
- ZNF230 | c.422A>G p.Q141R | Missense Mutation (SNP) | VAF 61/180 reads (34%) | SIFT tolerated (0.17); PolyPhen benign (0.003); catalogued as COSV101431872; called by muse, mutect2, varscan2
- ZNF492 | c.33G>T p.V11= | Splice Region (SNP) | VAF 66/294 reads (22%) | catalogued as COSV71761707; called by muse, mutect2, varscan2
- ZNF536 | c.3048G>T p.M1016I | Missense Mutation (SNP) | VAF 54/121 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.914); catalogued as COSV62820522; called by muse, mutect2, varscan2
- ZNF560 | c.1133G>T p.C378F | Missense Mutation (SNP) | VAF 67/173 reads (39%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.969); catalogued as COSV100038184; called by muse, mutect2, varscan2
- ZNF667 | c.1597G>A p.G533S | Missense Mutation (SNP) | VAF 60/104 reads (58%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.582); catalogued as COSV99409950; called by muse, mutect2, varscan2
- ZNF780B | c.904G>T p.E302* | Nonsense Mutation (SNP) | VAF 82/197 reads (42%) | catalogued as COSV99665131; called by muse, mutect2, varscan2
- ZNF804A | c.359T>A p.L120Q | Missense Mutation (SNP) | VAF 17/56 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV100166002; called by muse, mutect2, varscan2
- ZNF831 | c.428A>C p.K143T | Missense Mutation (SNP) | VAF 17/151 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.827); catalogued as COSV100925728, COSV64044530; called by muse, mutect2
- ZSCAN10 | c.1402G>C p.V468L (on ENST00000252463; = p.V523L on NM_032805.3) | Missense Mutation (SNP) | VAF 6/11 reads (55%) | SIFT tolerated (0.29); PolyPhen benign (0.07); catalogued as COSV52966662, COSV99373776; called by muse, mutect2, varscan2
- ABL1 | c.2352del p.R785Gfs*3 | Frame Shift Del (DEL) | VAF 34/63 reads (54%) | called by mutect2, pindel, varscan2
- ADAMTS6 | c.1671A>G p.I557M | Missense Mutation (SNP) | VAF 23/31 reads (74%) | SIFT deleterious (0); PolyPhen benign (0.089); called by muse, mutect2, varscan2
- ARHGAP17 | c.2058_2060delinsTT p.G687Sfs*39 (on ENST00000289968 / NM_001006634.3; = p.G609Sfs*39 on NM_018054.6) | Frame Shift Del (DEL) | VAF 56/146 reads (38%) | called by pindel, varscan2*
- DUOX1 | c.569G>T p.R190L | Missense Mutation (SNP) | VAF 6/10 reads (60%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by mutect2, varscan2
- GALNT13 | c.1520_1524del p.Y507Cfs*2 | Frame Shift Del (DEL) | VAF 41/115 reads (36%) | called by mutect2, pindel, varscan2
- LONRF1 | c.1401dup p.P468Sfs*21 | Frame Shift Ins (INS) | VAF 40/108 reads (37%) | called by mutect2, pindel, varscan2
- MPHOSPH8 | c.648del p.D219Mfs*3 | Frame Shift Del (DEL) | VAF 9/30 reads (30%) | called by mutect2, pindel, varscan2
- NBPF20 | c.262C>A p.Q88K | Missense Mutation (SNP) | VAF 28/435 reads (6%) | SIFT deleterious (0.01); PolyPhen benign (0); called by muse, mutect2
- PLCH1 | c.108dup p.G37Rfs*10 (on ENST00000340059 / NM_001130960.2; = p.G49Rfs*10 on NM_014996.4 and 1 other RefSeq transcript) | Frame Shift Ins (INS) | VAF 92/238 reads (39%) | called by mutect2, varscan2
- SAPCD1 | c.247C>G p.L83V | Missense Mutation (SNP) | VAF 9/149 reads (6%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.931); called by muse, mutect2
- SHCBP1L | c.1710+1del p.X570_splice | Splice Site (DEL) | VAF 57/195 reads (29%) | called by mutect2, pindel, varscan2
- SUPT20HL1 | c.1870G>A p.G624R | Missense Mutation (SNP) | VAF 17/29 reads (59%) | SIFT tolerated (0.22); PolyPhen benign (0.031); called by muse, mutect2, varscan2
- ZNF473 | c.1547_1550del p.E516Vfs*14 | Frame Shift Del (DEL) | VAF 44/129 reads (34%) | called by mutect2, pindel, varscan2
- ZNF605 | c.1295G>T p.G432V | Missense Mutation (SNP) | VAF 55/129 reads (43%) | SIFT tolerated (0.34); PolyPhen probably damaging (0.999); called by muse, varscan2
- ANK2 | c.7363C>T p.L2455= | Silent (SNP) | VAF 32/108 reads (30%) | catalogued as COSV99999113; called by muse, varscan2
- ASCL1 | c.582C>A p.S194= | Silent (SNP) | VAF 50/110 reads (45%) | catalogued as rs769602096, COSV57152265, COSV99901865; called by muse, varscan2
- CCDC85A | c.1179C>G p.L393= | Silent (SNP) | VAF 19/34 reads (56%) | catalogued as COSV101339340; called by muse, varscan2
- CFHR4 | c.1071A>G p.K357= (on ENST00000367416 / NM_001201551.2; = p.K111= on NM_006684.5) | Silent (SNP) | VAF 42/76 reads (55%) | catalogued as rs764077233, COSV99259364; called by muse, mutect2, varscan2
- CLDN15 | c.129C>T p.T43= | Silent (SNP) | VAF 19/51 reads (37%) | catalogued as COSV99778878, COSV99778976; called by muse, mutect2, varscan2
- CORO7 | c.2130C>T p.L710= | Silent (SNP) | VAF 24/60 reads (40%) | catalogued as rs749496892, COSV99227093; called by muse, mutect2, varscan2
- CPE | c.498G>C p.A166= | Silent (SNP) | VAF 16/37 reads (43%) | catalogued as COSV101291533, COSV68581245; called by muse, mutect2, varscan2
- CSMD2 | c.2514C>A p.L838= | Silent (SNP) | VAF 43/54 reads (80%) | catalogued as COSV99585047; called by muse, mutect2, varscan2
- DEPTOR | c.492C>A p.T164= | Silent (SNP) | VAF 76/153 reads (50%) | catalogued as COSV99637683; called by muse, mutect2, varscan2
- DST | c.708C>G p.S236= | Silent (SNP) | VAF 46/106 reads (43%) | catalogued as COSV100418889; called by muse, mutect2, varscan2
- DUOX1 | c.570G>T p.R190= | Silent (SNP) | VAF 6/10 reads (60%) | catalogued as COSV100367551; called by muse, mutect2, varscan2
- EIF2AK4 | c.498G>A p.R166= | Silent (SNP) | VAF 42/86 reads (49%) | catalogued as COSV99773914; called by muse, mutect2, varscan2
- GABRA5 | c.681G>A p.L227= | Silent (SNP) | VAF 24/55 reads (44%) | catalogued as COSV59475585, COSV59477804; called by muse, mutect2, varscan2
- GPR141 | c.111C>T p.S37= | Silent (SNP) | VAF 40/119 reads (34%) | catalogued as COSV100550203; called by muse, mutect2, varscan2
- GRIA2 | c.742T>C p.L248= | Silent (SNP) | VAF 50/136 reads (37%) | catalogued as COSV99642661; called by muse, mutect2, varscan2
- GRIN2A | c.531C>T p.F177= | Silent (SNP) | VAF 9/166 reads (5%) | catalogued as COSV58046709; called by muse, mutect2
- H3C13 | c.27C>G p.R9= | Silent (SNP) | VAF 52/146 reads (36%) | catalogued as rs781922786, COSV100516011, COSV58944970; called by muse, mutect2, varscan2
- IGKV3D-11 | c.198C>G p.L66= | Silent (SNP) | VAF 46/148 reads (31%) | called by muse, mutect2, varscan2
- LUM | c.24C>G p.L8= | Silent (SNP) | VAF 25/52 reads (48%) | catalogued as COSV99898846; called by muse, mutect2, varscan2
- MAGEB4 | c.45C>G p.R15= | Silent (SNP) | VAF 20/26 reads (77%) | catalogued as COSV100854583; called by muse, mutect2, varscan2
- MB21D2 | c.453G>C p.R151= | Silent (SNP) | VAF 31/104 reads (30%) | catalogued as rs763407821, COSV101164979; called by muse, mutect2, varscan2
- MSRA | c.669G>C p.G223= | Silent (SNP) | VAF 21/95 reads (22%) | catalogued as rs1283193062, COSV100412210; called by muse, mutect2, varscan2
- MYBPC1 | c.2340G>A p.E780= (on ENST00000550270 / NM_206820.2; = p.E787= on NM_002465.4) | Silent (SNP) | VAF 33/66 reads (50%) | catalogued as rs748190046, COSV100637688, COSV100637729; called by muse, mutect2, varscan2
- MYO3A | c.1803C>A p.L601= | Silent (SNP) | VAF 50/77 reads (65%) | catalogued as COSV99777877; called by muse, mutect2, varscan2
- NBEA | c.1029G>T p.R343= | Silent (SNP) | VAF 51/84 reads (61%) | catalogued as COSV100076131; called by muse, mutect2, varscan2
- NBEA | c.5085A>T p.T1695= | Silent (SNP) | VAF 50/80 reads (63%) | catalogued as COSV100076133; called by muse, mutect2, varscan2
- NECAB2 | c.627G>T p.A209= | Silent (SNP) | VAF 12/57 reads (21%) | catalogued as COSV100533791; called by muse, mutect2, varscan2
- OR2C3 | c.492C>A p.T164= | Silent (SNP) | VAF 20/48 reads (42%) | catalogued as COSV100825586; called by muse, mutect2, varscan2
- OR51B2 | c.906C>A p.I302= | Silent (SNP) | VAF 10/47 reads (21%) | catalogued as COSV100173230; called by muse, mutect2, varscan2
- OR51Q1 | c.546C>A p.L182= | Silent (SNP) | VAF 66/212 reads (31%) | catalogued as COSV100332786, COSV100332912; called by muse, mutect2, varscan2
- OR8K1 | c.84G>T p.G28= | Silent (SNP) | VAF 39/85 reads (46%) | catalogued as COSV99687019; called by muse, mutect2, varscan2
- PDZRN3 | c.1059G>A p.L353= | Silent (SNP) | VAF 50/69 reads (72%) | catalogued as COSV99726917; called by muse, mutect2, varscan2
- PLCL1 | c.1389A>G p.T463= | Silent (SNP) | VAF 32/85 reads (38%) | catalogued as COSV101406773; called by muse, mutect2, varscan2
- RP1 | c.6135T>C p.G2045= | Silent (SNP) | VAF 21/79 reads (27%) | catalogued as COSV99606008; called by muse, mutect2, varscan2
- RTBDN | c.369C>T p.F123= (on ENST00000393233 / NM_001270444.1; = p.F155= on NM_031429.2) | Silent (SNP) | VAF 9/13 reads (69%) | catalogued as rs1379940449, COSV100530677; called by muse, mutect2, varscan2
- RUBCNL | c.1899A>G p.K633= | Silent (SNP) | VAF 29/49 reads (59%) | catalogued as rs9562652, COSV100528788; called by muse, mutect2, varscan2
- SEC16B | c.69A>G p.P23= | Silent (SNP) | VAF 27/75 reads (36%) | catalogued as COSV100381155; called by muse, mutect2, varscan2
- SEMA4A | c.1722C>T p.S574= | Silent (SNP) | VAF 34/72 reads (47%) | catalogued as COSV100740400; called by muse, mutect2
- SEMA6D | c.2037A>G p.A679= (on ENST00000316364 / NM_153618.2; = p.A617= on NM_020858.2) | Silent (SNP) | VAF 71/198 reads (36%) | catalogued as rs564474645, COSV100316315; called by muse, mutect2, varscan2
- SLC22A8 | c.1536G>T p.L512= | Silent (SNP) | VAF 23/60 reads (38%) | catalogued as COSV100267667; called by muse, mutect2, varscan2
- SLITRK2 | c.2304C>T p.S768= | Silent (SNP) | VAF 16/218 reads (7%) | catalogued as rs782444429, COSV59422848; called by muse, mutect2
- STK25 | c.1212G>A p.L404= | Silent (SNP) | VAF 64/183 reads (35%) | catalogued as rs536849374, COSV99883703; called by muse, mutect2, varscan2
- SUPT5H | c.2538G>T p.P846= | Silent (SNP) | VAF 71/193 reads (37%) | catalogued as COSV100781887; called by muse, mutect2, varscan2
- TPCN2 | c.237G>A p.S79= | Silent (SNP) | VAF 14/50 reads (28%) | catalogued as rs753904192, COSV99593114; called by muse, mutect2, varscan2
- TRGC1 | c.492G>T p.T164= | Silent (SNP) | VAF 38/140 reads (27%) | called by muse, varscan2
- TTN | c.61629C>G p.G20543= (on ENST00000591111; = p.G13119= on NM_003319.4) | Silent (SNP) | VAF 10/31 reads (32%) | catalogued as COSV100591255; called by muse, mutect2, varscan2
- TTN | c.17340C>T p.A5780= (on ENST00000591111; = p.A4853= on NM_133378.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 21/77 reads (27%) | catalogued as COSV60293514, COSV60442464; called by muse, mutect2, varscan2
- ZBTB41 | c.1263G>A p.E421= | Silent (SNP) | VAF 19/63 reads (30%) | catalogued as rs752381736, COSV100962754; called by muse, mutect2, varscan2
- BLACAT1 | c.-36-7324G>A | Intron (SNP) | VAF 60/147 reads (41%) | catalogued as COSV100762086; called by muse, mutect2, varscan2
- CIRBP | c.-7+567A>T | Intron (SNP) | VAF 43/54 reads (80%) | catalogued as COSV100309649; called by muse, mutect2, varscan2
- FAM21FP | n.365G>T | RNA (SNP) | VAF 49/184 reads (27%) | called by muse, mutect2, varscan2
- LINC02843 | n.236G>T | RNA (SNP) | VAF 61/128 reads (48%) | called by muse, mutect2, varscan2
- PYY3 | n.103G>T | RNA (SNP) | VAF 12/17 reads (71%) | called by muse, mutect2, varscan2
- TUBB7P | n.801G>T | RNA (SNP) | VAF 24/72 reads (33%) | called by muse, mutect2, varscan2
